Surgical pathology report (de-identified scan), TCGA case TCGA-UW-A7GK, project TCGA-KICH (Kidney Chromophobe), tissue source site University of North Carolina, specimen TCGA-UW-A7GK-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

Diagnosis:

Kidney, right, nephrectomy.

- Renal cell carcinoma, chromophobe type.
- Furhman nuclear grade: 2.
- Tumor size: 3.3 cm.
- Extent of involvement: Tumor is confined to the kidney.
- Angiolymphatic and perineural invasion: Absent.
- Margins: Negative.

Clinical History:

The patient is a -year-old Caucasian female with a right renal mass who undergoes laparoscopic nephrectomy.

Gross Description:

Received in a formalin-filled container, additionally labeled "R kidney".

Specimen fixation: Formalin

Type of specimen: Partial laparoscopic
nephrectomy

Side of specimen: Right

Size and weight of specimen: 185 grams, 10 x 5.3 x 3.2 cm (post fixation) kidney with a 14 x 5 x 2.5 cm portion of attached perinephric fat. This fat is only attached near the hilum and focally at the superior and inferior poles. It is not clear grossly how this fat is oriented on the specimen.

Presence/absence of adrenal gland: Absent

Tumor description/site: There is an upper pole, medullary mass, which is compressing both the medulla, cortex and pelvis. The mass is variegated, bright orange, and dark brown and hemorrhagic and soft. The renal capsule is intact and the external surface of the kidney overlying the tumor is inked black.

Tumor size: 3.3 x 2.5 x 1.3 cm

Presence/absence of multicentricity: Absent

ICD O-3

Carcinoma, renal cell
Chromophobe type 8317/3

Site R Kidney NOS 64.9

JW 9/24/13

[page 2 of 2]
Confinement/non-confinement to the kidney: Confined

Extent of invasion:

Perirenal adipose tissue: Tumor does not grossly involve

Gerota's fascia: Tumor does not grossly involve

Renal vein: Tumor does not grossly involve

Ureter: Tumor does not grossly involve

Other organs: N/A

Surgical margins:

Perirenal adipose tissue: Negative

Renal vein: Negative

Renal artery: Negative

Ureter: Negative

Description of kidney away from tumor: The remainder of the renal parenchyma is brown/tan with a distinct corticomedullary junction and the cortex measuring 3 mm on average and the medulla measuring 1.5 cm. There is no evidence of papillary necrosis. The external upper pole is remarkable for a 1.3 x 0.2 cm small caliber tubular structure (? Vessel) by extending out from the upper pole, hilar surface.

Lymph nodes (hilar): The hilar adipose tissue is palpated for lymph node candidates, however, no lymph nodes are identified.

Comment: The perirenal adipose tissue is unremarkable except for a hemorrhagic external surface. The fat is freely moveable over the surface.

Block Summary:

A1 - Ureter and hilar vascular margins, en face

A2 - Tumor and black inked external surface, cross section of upper pole, small caliber vascular structure

A3 - Additional tumor and capsule

A4 - Tumor and normal kidney

A5 - Normal kidney, lower pole

Light Microscopy:

Light microscopic examination is performed by Dr.

Reviewed/Initials	8/31/13	8/30/13

Immunostains were performed on A3. The tumor cells show strong reactivity for CD117 and focal staining for CK7. Stains for CK20, CD10, CD15, and vimentin are all negative. These findings support a diagnosis of chromophobe RCC and argue against a diagnosis of oncocytoma.

Histologic tumor type/subtype: renal cell carcinoma, chromophobe

Histologic grade (if applicable): grade 2 of 4; focally, there is higher grade atypia

Source: NCI Genomic Data Commons file e405f94d-a3af-49b8-be98-fe6555a2760a (TCGA-UW-A7GK.B8E026C7-B1AA-43DA-8E9C-099D312733CC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).